Somatic mutation profile of tumor specimen TCGA-YL-A8SL-01B (aliquot TCGA-YL-A8SL-01B-21D-A377-08) from TCGA case TCGA-YL-A8SL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 74.0 years (27,033 days).
Specimen TCGA-YL-A8SL-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 672ebd3d-2bd8-406e-861e-5d0a4416213e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8SL-10A (Blood Derived Normal), aliquot TCGA-YL-A8SL-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d846f94-f95d-49ae-94c7-302f4198497e

The open-access MAF lists 43 somatic variants for this specimen: 36 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 6, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K4 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV62255770, COSV62259440; called by muse, mutect2, varscan2
- ARHGAP20 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99504695; called by muse, mutect2, varscan2
- CHST12 | c.1148A>G p.K383R | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV99324568; called by muse, mutect2, varscan2
- CLPTM1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs769057466, COSV61612402; called by muse, mutect2, varscan2
- CLSTN1 | c.1238T>A p.M413K (on ENST00000377298 / NM_001009566.3; = p.M403K on NM_014944.4) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.844); catalogued as COSV100790695; called by muse, mutect2, varscan2
- COL1A2 | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs765271962, COSV51958062, COSV51959307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSNK1G1 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 48/129 reads (37%) | catalogued as COSV100282245; called by muse, mutect2, varscan2
- GPNMB | c.1643C>T p.A548V (on ENST00000381990 / NM_001005340.2; = p.A536V on NM_002510.3) | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as COSV99326640; called by muse, mutect2, varscan2
- GPR32 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.261); catalogued as COSV99567297; called by muse, mutect2, varscan2
- KIF25 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV100596426; called by muse, mutect2, varscan2
- LILRB1 | c.719C>T p.S240F (on ENST00000427581; = p.S204F on NM_006669.6) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV100207566; called by muse, varscan2
- NRIP1 | c.865A>G p.N289D | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.295); catalogued as COSV100012880; called by muse, mutect2, varscan2
- OLFML3 | c.906T>G p.D302E | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.334); catalogued as rs760201713, COSV100233159; called by muse, mutect2, varscan2
- OR4L1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs980108570, COSV59848892; called by muse, mutect2, varscan2
- PIK3CB | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100006173, COSV56683125, COSV56690507; called by muse, mutect2
- PLA2G4A | c.1427C>G p.S476* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV100820618; called by muse, mutect2, varscan2
- POMGNT1 | c.14A>C p.K5T | Missense Mutation (SNP) | VAF 37/92 reads (40%) | PolyPhen benign (0.003); catalogued as COSV100915715; called by muse, mutect2, varscan2
- PPP2R5A | c.518C>G p.P173R | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV99806814; called by muse, mutect2, varscan2
- PRDM15 | c.2771C>T p.A924V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs745721908, COSV99520529; called by mutect2, varscan2
- PTPRC | c.2800A>C p.K934Q | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.258); catalogued as COSV100722850; called by muse, mutect2, varscan2
- RBL2 | c.866A>G p.E289G | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100043865; called by muse, mutect2, varscan2
- SEC22A | c.914A>C p.Y305S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.188); catalogued as COSV59374692; called by muse, mutect2, varscan2
- SLC16A6 | c.67T>C p.W23R | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100517360; called by muse, mutect2, varscan2
- SMPD2 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57806834, COSV99238068; called by muse, mutect2, varscan2
- SMYD2 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100873273; called by muse, mutect2, varscan2
- SPTA1 | c.4238C>T p.A1413V | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); catalogued as COSV100934086; called by muse, mutect2
- SRSF4 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1441731561, COSV65695639; called by muse, mutect2, varscan2
- TAS1R2 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as rs199701205, COSV64745645; called by muse, mutect2, varscan2
- TBX15 | c.1132G>C p.A378P (on ENST00000369429 / NM_001330677.2; = p.A272P on NM_152380.3) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99254461; called by muse, mutect2, varscan2
- TGM6 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs986690561, COSV52478980; called by muse, mutect2, varscan2
- TRBV6-1 | c.336C>G p.S112R | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as rs1287248168; called by muse, mutect2, varscan2
- USH2A | c.5570A>C p.Q1857P | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100238715; called by muse, mutect2, varscan2
- USP9X | c.6586C>T p.L2196F | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61065937, COSV61075812; called by muse, mutect2, varscan2
- CASR | c.1759_1764del p.S587_S588del (on ENST00000490131; = p.S664_S665del on NM_000388.4) | In Frame Del (DEL) | VAF 29/79 reads (37%) | called by mutect2, pindel, varscan2
- IDE | c.845del p.N282Mfs*23 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- IFNA16 | c.89del p.H30Pfs*9 | Frame Shift Del (DEL) | VAF 34/139 reads (24%) | called by mutect2, pindel, varscan2
- ADGRF1 | c.2556G>A p.K852= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs961690168, COSV99347466; called by muse, mutect2, varscan2
- ADPRM | c.924C>G p.A308= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as COSV100541436; called by muse, mutect2, varscan2
- GSX2 | c.33C>A p.I11= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV100482596; called by muse, mutect2
- PI4KA | c.3486C>A p.T1162= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs1275141288, COSV99747400; called by muse, mutect2, varscan2
- PRSS54 | c.780C>T p.Y260= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs367759301; called by muse, mutect2, varscan2
- SH3D21 | c.1824G>A p.E608= (on ENST00000453908 / NM_001162530.2; = p.E497= on NM_024676.5) | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as rs760923400, COSV54635199, COSV99584166; called by muse, mutect2, varscan2
- TLE4 | c.46-348del | Intron (DEL) | VAF 10/22 reads (45%) | catalogued as rs1443037296; called by mutect2, varscan2
